Somatic mutation profile of tumor specimen MMRF_1522_1_BM_CD138pos (aliquot MMRF_1522_1_BM_CD138pos_T1_KBS5U_L03493) from MMRF case MMRF_1522, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.8 years (15,624 days).
Specimen MMRF_1522_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa296eb2-489b-46f1-b168-b614dd3a2785.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1522_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1522_1_PB_Whole_C2_KBS5U_L03481; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b39c2da-98af-4922-86ff-f8ec52919c45

The open-access MAF lists 90 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 28, Silent 12, Intron 10, 5'UTR 3, 3'Flank 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as rs781910376, COSV61004901, COSV61005393; called by muse, mutect2, varscan2
- DNAJC2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs776862127, COSV50786630; called by muse, mutect2, varscan2
- DSG3 | c.2047A>G p.N683D | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs200076592; called by muse, mutect2, varscan2
- GATA3 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV60521021; called by muse, mutect2
- IGFN1 | c.3293G>A p.R1098H (on ENST00000295591 / NM_001367841.1; = p.R3555H on NM_001164586.2) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs755448825; called by muse, mutect2, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGLV4-3 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs772217932; called by muse, varscan2
- LMNTD2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs758825364; called by muse, mutect2, varscan2
- NEFM | c.1092G>T p.Q364H | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV55332608; called by muse, mutect2, varscan2
- PALM3 | c.1001C>A p.S334Y (on ENST00000340790; = p.S349Y on NM_001145028.2) | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1342375079; called by muse, mutect2, varscan2
- PCLO | c.5141G>A p.G1714E | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1235952844; called by muse, mutect2
- TCERG1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57034199; called by muse, mutect2, varscan2
- ACP6 | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, varscan2
- CAVIN3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCN5 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CSE1L | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTXN3 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYTIP | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DPF1 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOSB | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- IGKV2-29 | n.51-2A>G | Splice Site (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- NKAP | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOXA1 | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL7 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RAB14 | c.120T>G p.C40W | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SHANK2 | c.2386A>G p.T796A | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SLC7A14 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.4774T>A p.S1592T | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATP9B | c.1386G>A p.L462= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as rs774044652, COSV56964751; called by muse, mutect2, varscan2
- CACNA1F | c.5025C>T p.S1675= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs371675126; called by muse, mutect2, varscan2
- HELZ2 | c.424C>T p.L142= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV64410029; called by muse, mutect2
- LRFN2 | c.495G>A p.P165= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs751384640; called by muse, mutect2, varscan2
- OR2C1 | c.877C>A p.R293= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- PCBD1 | c.51G>T p.L17= | Silent (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- RASGEF1A | c.1056C>T p.N352= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- ROBO1 | c.4527A>T p.P1509= | Silent (SNP) | VAF 76/170 reads (45%) | called by muse, mutect2, varscan2
- SHISA5 | c.654C>T p.A218= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs771121366, COSV56497026; called by muse, mutect2, varscan2
- SPACA1 | c.192G>A p.P64= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs754914513, COSV52761542; called by muse, mutect2, varscan2
- TASOR | c.306C>T p.I102= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs1194596087; called by muse, mutect2, varscan2
- TLE1 | c.1752C>T p.P584= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs375550899; called by muse, mutect2, varscan2
- ABCF3 | c.1658+14G>T | Intron (SNP) | VAF 16/119 reads (13%) | catalogued as rs751751108; called by mutect2, varscan2
- AC064805.2 | n.2188G>A | RNA (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- ACP6 | c.480-27G>T | Intron (SNP) | VAF 27/56 reads (48%) | called by muse, varscan2
- ANKRD42 | c.*829dup | 3'UTR (INS) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- ANO7 | c.*934G>A | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*2014T>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ARX | c.*856A>C | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- ATP9A | c.*2026C>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | catalogued as rs529025900; called by muse, mutect2, varscan2
- C15orf54 | n.1460G>T | RNA (SNP) | VAF 25/144 reads (17%) | catalogued as rs932111194; called by muse, mutect2, varscan2
- CACNA2D4 | c.2922-101G>A | Intron (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.*1413T>G | 3'UTR (SNP) | VAF 52/82 reads (63%) | called by muse, varscan2
- DNAJB9 | c.*723T>C | 3'UTR (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- EDNRB | c.*6_*8del | 3'UTR (DEL) | VAF 36/178 reads (20%) | catalogued as rs769151750; called by pindel, varscan2
- ELAPOR2 | c.*390C>T | 3'UTR (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- ERMARD | c.1521-65G>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ERP27 | c.*229T>G | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2
- GALNT1 | c.*911T>G | 3'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- HFE | c.*519C>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- HPN | c.-529G>A | 5'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- KDM6A | c.*674G>A | 3'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- LY96 | c.-7T>C | 5'UTR (SNP) | VAF 49/237 reads (21%) | catalogued as rs1459007420; called by muse, mutect2, varscan2
- MAEA | c.*228C>A | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- MINAR1 | c.*2721G>T | 3'UTR (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- MTDH | c.*1918T>G | 3'UTR (SNP) | VAF 5/134 reads (4%) | called by muse, mutect2
- MYO10 | c.2169+16A>G | Intron (SNP) | VAF 22/39 reads (56%) | called by mutect2, varscan2
- NCAM2 | c.*4210A>G | 3'UTR (SNP) | VAF 16/158 reads (10%) | catalogued as rs1351028227; called by muse, mutect2, varscan2
- OSTF1 | c.*343G>A | 3'UTR (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- PCDH11X | c.*749G>T | 3'UTR (SNP) | VAF 165/358 reads (46%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+4380G>A | Intron (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*720A>G | 3'UTR (SNP) | VAF 40/79 reads (51%) | catalogued as rs1428312922; called by muse, mutect2, varscan2
- PTPN20 | chr10:47002034 G>T | 3'Flank (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.*2112A>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- RP2 | c.*1667T>A | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- RTKN2 | c.*1179C>A | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- SAMM50 | c.*80C>T | 3'UTR (SNP) | VAF 49/118 reads (42%) | catalogued as rs1162656691; called by muse, mutect2, varscan2
- SDC3 | c.257-235C>T | Intron (SNP) | VAF 17/76 reads (22%) | catalogued as rs1044168519; called by mutect2, varscan2
- SGCA | c.983+1042C>T | Intron (SNP) | VAF 60/125 reads (48%) | catalogued as rs1489661267; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145828412 G>A | 3'Flank (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.*983del | 3'UTR (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- TBC1D22B | c.*1229T>C | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- TH | c.*91G>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- TMCO5A | c.570-174T>G | Intron (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- TRPV3 | c.*540G>A | 3'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- TSC22D3 | c.*318G>C | 3'UTR (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- TSGA10 | c.-443T>C | 5'UTR (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- TVP23C | c.*576dup | 3'UTR (INS) | VAF 3/28 reads (11%) | called by muse*, pindel
- VEGFC | c.*219A>C | 3'UTR (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- ZNF135 | c.*1228_*1229insT | 3'UTR (INS) | VAF 36/90 reads (40%) | called by mutect2, varscan2
- ZNF451 | c.186+7921A>G | Intron (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
